CCDI case PBBREU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/bf24e564-445c-4186-a548-27f91a07addf

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Sertoli cell tumor, NOS: ICD-O-3 morphology code: 8640/1; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 17.6 years (6,412 days).

Biospecimens (3 samples)
- Sample 0DETFH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DETFK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DETFP: Tissue type: Tumor; Specimen type: Solid Tissue.
